Surgical pathology report (de-identified scan), TCGA case TCGA-4A-A93Y, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-4A-A93Y-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]	Result ID: [REDACTED]	Accession: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: F	Account: [REDACTED]	Date Collected: [REDACTED]
MRN: [REDACTED]	Patient [REDACTED]	Date Received: [REDACTED]
Requested by: [REDACTED]		Date Reported: [REDACTED]

Clinical Data: Left renal mass

FINAL PATHOLOGIC DIAGNOSIS

Left kidney, radical nephrectomy with adrenal gland:
Papillary renal cell carcinoma.
Unremarkable adrenal gland.

SYNOPTIC REPORT

Tumor site:	Left kidney, superior pole
Tumor size:	Greatest dimension: 12.5 cm
Tumor focality:	Unifocal
Microscopic extent of tumor:	Tumor limited to kidney
Histologic type:	Papillary renal cell carcinoma, type 2
Margins:	Uninvolved by invasive carcinoma
Gerota's fascial margin:	Negative for tumor
Renal vein margin:	Negative for tumor
Ureteral margin:	Negative for tumor
Regional lymph nodes:	One hilar lymph node is negative for tumor (0/1)
Additional findings:	Unremarkable adrenal gland
Pathologic Tumor Stage:	pT2b pN0

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site @ Kidney NOS Cat 4.9
JW 3/20/14

Pathologist, Electronic Signature

Intradepartmental consultation:

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

Left kidney: In formalin labeled "left kidney" is a 762 gram, 16.5 x 11.5 x 10 cm nephrectomy specimen with attached perinephric fat, attached 8 cm of ureter, and a 6 cm attached adrenal gland. Upon sectioning in the superior pole, there is a 12.5 cm in greatest dimension lobulated tumor. The cut surfaces of the tumor are lobulated mottled orange-red to brown, with diffuse hemorrhage and necrosis. The tumor abuts and elevates the renal capsule; however, no definitive invasion beyond the capsule into the perinephric fat is appreciated. The tumor also appears to abut the renal pelvic/calyceal mucosa, with no gross invasion into or through the mucosa. No involvement of the ureter or gross involvement of the vasculature is appreciated. The remaining cut surfaces are pink-brown renal parenchyma with a defined corticomedullary junction. The cut surfaces of the adrenal gland are mottled grey-orange to brown, with no tumor involvement. There is a 1.3 cm lymph node at the kidney hilum.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

The perinephric soft tissue margin is inked black. Representative sections submitted in six cassettes, as follows: A - ureter and vascular margins; B - tumor to renal capsule and inked perinephric soft tissue margin; C - tumor to renal capsule; D - tumor to renal pelvis/calices; E - uninvolved kidney and adrenal gland; and F - hilar lymph node, bisected.

Following initial microscopic evaluation, additional sections of tumor are submitted as G-I.

CPT CODE(S):

88309, 88307

ICD-9 CODE(S):

[1890]

FACILITY:

END OF REPORT

Source: NCI Genomic Data Commons file b667024f-9e08-42dc-9e9e-c0bf01703830 (TCGA-4A-A93Y.3552E70E-B26A-426D-993C-0D1A3CC9442B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).